CCDI case PBCFKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b5409cb8-9d7e-4f4b-93a5-9efb9bc52066

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,079 days).

Biospecimens (3 samples)
- Sample 0DR6XR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR6YE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR7YD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
